Gene-level copy-number profile of tumor specimen C3N-03011-01 (profiled together with C3N-03011-02, C3N-03011-04) from CPTAC case C3N-03011, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 62.6 years (22,872 days).
Specimen C3N-03011-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1d209153-1f23-42c4-b684-3983a1c8e2e3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03011-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/4b04a691-d458-4fa9-aafa-5b876b730340

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,274; copy number 1: 25,889; copy number 2: 31,348; copy number 3: 16; copy number 4: 3; copy number 6: 255; copy number 7: 74; copy number 13: 49.

Homozygous deletions (total copy number 0; autosomes only): 1,257 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes (within-gene range 0–2): RNU6-904P, RPS16P3.
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–1): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr4:78,887,127–78,939,438, 2 genes (within-gene range 0–1): PAQR3, RN7SL127P.
- chr9:21,695,176–22,128,103, 16 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:39,355,669–39,655,531, 10 genes: SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3, FKBP4P2, SDR42E1P1, ATP5F1AP8.
- chr9:39,816,599–39,874,562, 1 gene (within-gene range 0–1): BX664615.2.
- chr9:61,190,003–61,642,494, 10 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr14:102,770,040–102,774,791, 1 gene: AL132801.1.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–1): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–1): IGHV3-43.
- chr16:34,941,977–90,222,851, 1,203 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 378 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:68,891,276–85,627,922, 378 genes, copy number 6–13 (within-gene range 1–13) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 23,052. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
